Surgical pathology report (de-identified scan), TCGA case TCGA-18-3414, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3414-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

1. Lung: RT. UPPER LOBE NODULE- QUICK SECTION
2. LUNGS: Right middle lobe nodule/Q
3. Lymph node: Interlobar ST11R/
4. Lymph node: Interlobar ST11R
5. Lymph node: Right TB angle ST10R
LUNGS: RLL- bronchial resection margin
. LUNGS: RUL margin
8. Bone: Anterior margin - rib 5th
9. Bone: Anterior margin - 4th rib
10. Bone: Resection margin - 3rd rib
11. Bone: Ribs #3 and #4
12. LUNGS: Resection margin 4th intercostal space
13. LUNGS: Resection margin 5th intercostal space

DIAGNOSIS

1. Right upper lobe lung wedge resection:
- Squamous cell carcinoma with invasion into attached chest wall tissue. (pM1)
2. Right middle lobe nodule wedge resection:
- Metastatic squamous cell carcinoma. (pM1)
3. Interlobar ST11R lymph node:
- Positive for metastatic squamous cell carcinoma. (pN1)
4. Interlobar ST11R:
- Negative for malignancy, lymph node.
5. Right TB angle ST10R:
- Negative for malignancy, lymph node.
- Right lower lobe lung lobectomy:
- Squamous cell carcinoma, moderately differentiated, 4.3 cm in greatest

[page 2 of 6]
[REDACTED]

diameter.

- Visceral pleura invasion noted.
- 1 out of 8 lobar peribronchial lymph node positive for metastasis.
- Bronchial resection margin negative for tumor.
- Satellite (1 cm away) intralobar metastatic nodule, 0.5 cm in greatest diameter. (pT4)
- Remaining lung parenchyma shows mild-moderate emphysema.

7. Right upper lobe margin:

- Negative for malignancy, emphysema and focal organizing pneumonia.

Anterior margin 5th rib:

Pending.

9. Anterior margin 4th rib:

- Pending.

10. Resection margin 3rd rib:

- Negative for malignancy, fibrosis.

11. Ribs #3 and #4:

- Negative for malignancy, skeletal muscle and fibroadipose tissue with fibrosis.

12. Resection margin 4th intercostal space:

- Negative for malignancy, fibroadipose tissue.

13. Resection margin 5th intercostal space:

- Negative for malignancy, fibroadipose tissue with nerve trunk.

COMMENT

All tumors show similar histology, thus tumors in right upper and middle lobes are consistent with metastasis.

[REDACTED]

CLINICAL HISTORY
CA LUNG

[page 3 of 6]
GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "right upper lobe nodule QS" contains a wedge of lung tissue received fresh in the measuring 6 x 2.5 x 1.7 cm. There is a staple line along one side. The visceral pleura is intact and the partly covered by adhered fibrofatty tissue. On sectioning there is a firm non-circumscribed gray-tan nodular lesion that grossly extends beyond the visceral pleura and into the adhered fibrofatty tissue. The lesion measures approximately 5.5 cm in maximum diameter and extends grossly to within 0.3 cm of the staple line margin. Very minimal peripheral normal lung tissue is identified. A representative section is examined at intraoperative consultation by frozen section. Representative sections are submitted as follows:

1A frozen section resubmitted

1B shaved resection margin at staple line

1C,1D tumor with adhered fibrofatty tissue on the pleura.

2. The specimen container labeled with the patient's name and as "right middle lobe nodule QS" contains a piece of lung tissue measuring approximately 1.5 cm in maximum diameter. There is a 0.1 cm nodule in the sub pleura. A representative section to include the nodule is examined at intraoperative consultation by frozen section.

2A frozen section resubmitted

3. The specimen container labeled with the patient's name and as "interlobar ST11R/QS" contains a piece of a soft tissue measuring up to 1 cm in diameter. It is examined in toto at intraoperative consultation by frozen section.

3A frozen section resubmitted.

4. The specimen container labeled with the patient's name and as "interlobar ST 11R" contains one gray-black lymph node received in a 10% buffered formalin. It measures 1.4 x 0.6 x 0.3 cm.

4A submitted in toto

5. The specimen container labeled with the patient's name and as "right TB angle ST 10R" contains one gray-black lymph node received in 10% buffered formalin. It measures 1 x 0.6 x 0.3 cm.

5A submitted in toto.

[page 4 of 6]
6. The specimen container labeled with the patient's name and as "right lower lobe -- Bronchial resection margin/QS" contains a lobe of lung received in a 10% buffered formalin. It measures 15 x 10 x 5.5 cm. The visceral pleura is intact. There is a puckered somewhat indurated area within the superolateral aspect and the adjacent visceral pleura appears somewhat edematous. The bronchial resection margin is examined en face at intraoperative consultation by frozen section. On sectioning the lung a peripheral tumor mass is present within the puckered area. The tumor measures 4.3 cm in the fresh state and 3.9 cm post formalin fixation. It is firm and tan-gray. Grossly it extends right to the puckered pleura. It is 2.5 cm away from the bronchial resection margin. Approximately 1 cm away from the tumor there are two solitary gray-black to tan black nodules measuring 0.3 and 0.5 cm respectively. The tan black nodule abuts the pleura. No other nodules grossly identified. The remaining parenchyma shows some mild emphysematous changes. Several lobar lymph nodes are retrieved the largest measuring 0.7 cm. Representative sections are submitted as follows:

6A bronchial resection margin, frozen section resubmitted
6B two lobar lymph nodes
6C three lobar lymph nodes
6D one lobar lymph node bisected
6E-6G large tumor with puckered pleura
6H one half of the 0.5 cm tan black nodule
6I the remaining one half of the tan black nodule and the 0.3 cm gray-black nodule
6J, 6K nontumorous lung parenchyma to include emphysematous area

7. The specimen container labeled with the patient's name and as "right upper lobe margin" contains two wedges of lung tissue received in a 10% buffered formalin. They measure 2.5 x 0.6 x 0.4 cm and 4 x 1.5 x 1 cm. Each has a staple line present. The lung parenchyma is tan-gray with anthracotic pigment admixed. No lesions grossly identified. The visceral pleura is somewhat rough.

7A, 7B representative sections from both pieces submitted.

8. The specimen container labeled with the patient's name and as "anterior margin -- fifth rib" contains one piece of grossly unremarkable tan bone received in 10% buffered formalin. It measures 1.5 x 0.6 x 0.5 cm. It is decalcified and bisected.

1. submitted in toto

[page 5 of 6]
[REDACTED]

9. The specimen container labeled with the patient's name and as "anterior margin -- fourth rib" contains one piece of grossly unremarkable tan bone received in a 10% buffered formalin. It measures 1.5 x 0.8 x 0.6 cm. it is decalcified and bisected.

9A submitted in toto

10. The specimen container labeled with the patient's name and as "resection margin third rib" contains two pieces of yellowish tan soft tissue and bone received in 10% buffered formalin. They measure 0.3 x 0.2 x 0.2 cm each.

10A submitted in toto.

11. The specimen container labeled with the patient's name and as "ribs three and four" contains one piece of unoriented tissue consisting of two tan ribs with attached fibrofatty tissue and muscle received in 10% buffered formalin. It measures 7.5 x 5 x 1.8 cm. The surface of the soft tissue is painted with silver nitrate. On sectioning no gross abnormality noted.

11A,11B representative soft tissue submitted.

12. The specimen container labeled with the patient's name and as "resection margin forth intercostal space" contains one piece of tan-brown soft tissue received in 10% buffered formalin. It measures 0.7 x 0.5 x 0.3 cm.

12A submitted in toto

13. The specimen container labeled with the patient's name and as "resection margin fifth intercostal space" contains one piece of yellowish to tan-brown soft tissue received in 10% buffered formalin. It measures 1.5 x 0.6 x 0.4 cm.

13A submitted in toto.

[REDACTED]

QUICK SECTION

1A - "SQUAMOUS CELL CARCINOMA"

2A - "POST FOR SCC"

3A - "MET SQ. CELL CA"

4 - "NEGATIVE"

[REDACTED]

[page 6 of 6]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Addendum Status: Signed Out

[REDACTED]

Addendum Diagnosis

8, 9. Bone, anterior margins, 5th and 4th ribs:

- Negative for malignancy, normal bone and marrow. (x2)

Source: NCI Genomic Data Commons file 1ce06d71-7834-4265-ad33-8a6e099c1882 (TCGA-18-3414.F0BD5A6E-4EBF-4859-B139-80FBB3A54DAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).